Somatic mutation profile of tumor specimen TCGA-BG-A2AE-01A (aliquot TCGA-BG-A2AE-01A-11D-A16D-09) from TCGA case TCGA-BG-A2AE, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IB; Tumor grade: G3; Age at diagnosis: 57.7 years (21,069 days).
Specimen TCGA-BG-A2AE-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6fa8665f-3313-49c7-9e02-790119a6210d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BG-A2AE-10A (Blood Derived Normal), aliquot TCGA-BG-A2AE-10A-01D-A16D-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6071f7f9-c681-43e7-a121-b1b3ba51bd70

The open-access MAF lists 64 somatic variants for this specimen: 47 protein-altering or splice-affecting, 17 silent.
By variant classification: Missense Mutation 37, Silent 17, Nonsense Mutation 4, In Frame Del 2, Splice Region 1, Frame Shift Ins 1, Frame Shift Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARID1A | c.4003C>T p.R1335* | Nonsense Mutation (SNP) | VAF 19/50 reads (38%) | hotspot (GDC flag); catalogued as rs387906846, CM122485, COSV61371872; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ATM | c.5497-1G>A p.X1833_splice | Splice Site (SNP) | VAF 27/91 reads (30%) | catalogued as rs876660245, COSV53739044, COSV53781881; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 51/97 reads (53%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1637A>G p.Q546R | Missense Mutation (SNP) | VAF 34/86 reads (40%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.934); catalogued as rs397517201, COSV55875400, COSV55876869, COSV55877455; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ACAP3 | c.1410G>C p.L470= | Splice Region (SNP) | VAF 6/50 reads (12%) | catalogued as COSV57645545; called by muse, mutect2, varscan2
- ACSS1 | c.1789G>A p.V597M | Missense Mutation (SNP) | VAF 27/75 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.22); catalogued as COSV60225937; called by muse, mutect2, varscan2
- AQP6 | c.788C>T p.A263V | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs766565532, COSV59646848; called by muse, varscan2
- BMP5 | c.977G>T p.R326L | Missense Mutation (SNP) | VAF 59/149 reads (40%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.988); catalogued as COSV100895985, COSV63707374; called by muse, mutect2, varscan2
- BRS3 | c.32A>G p.Q11R | Missense Mutation (SNP) | VAF 21/79 reads (27%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0.024); catalogued as COSV65711412; called by muse, mutect2, varscan2
- CABP5 | c.130C>T p.R44* | Nonsense Mutation (SNP) | VAF 22/57 reads (39%) | catalogued as rs750592102, COSV53152630, COSV53154424; called by muse, mutect2, varscan2
- COLEC12 | c.1885G>A p.E629K | Missense Mutation (SNP) | VAF 24/59 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.057); catalogued as COSV68374791; called by muse, mutect2, varscan2
- CYFIP1 | c.1094G>A p.R365H | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.715); catalogued as rs771703298; called by muse, mutect2, varscan2
- CYSLTR1 | c.933G>C p.K311N | Missense Mutation (SNP) | VAF 25/76 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.005); catalogued as COSV64821508; called by muse, mutect2, varscan2
- EFCAB2 | c.673T>C p.Y225H (on ENST00000366522; = p.Y89H on NM_032328.3) | Missense Mutation (SNP) | VAF 18/138 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.965); catalogued as COSV63658962; called by muse, mutect2, varscan2
- EPHB1 | c.910C>G p.R304G | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.991); catalogued as COSV67674097; called by muse, mutect2, varscan2
- FPGT | c.589G>A p.D197N | Missense Mutation (SNP) | VAF 36/92 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.042); catalogued as COSV63835118, COSV63844780; called by muse, mutect2, varscan2
- GLRX3 | c.844G>A p.D282N | Missense Mutation (SNP) | VAF 61/198 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.985); catalogued as rs751236022, COSV58691613, COSV58694969; called by muse, mutect2, varscan2
- GRIA3 | c.857G>C p.R286P | Missense Mutation (SNP) | VAF 23/58 reads (40%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.717); catalogued as COSV52068717, COSV52084228; called by muse, mutect2, varscan2
- HUNK | c.1160G>A p.R387H | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.15); catalogued as rs780565997, COSV54235641; called by muse, mutect2
- IRF5 | c.323G>A p.R108Q | Missense Mutation (SNP) | VAF 21/47 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.413); catalogued as rs769606450, COSV50863185; called by muse, mutect2, varscan2
- KCNK9 | c.905A>T p.Y302F | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.943); catalogued as COSV57289605; called by muse, mutect2, varscan2
- LAMB4 | c.3316G>A p.G1106S | Missense Mutation (SNP) | VAF 45/75 reads (60%) | SIFT tolerated (0.29); PolyPhen benign (0.012); catalogued as rs146465702; called by muse, mutect2, varscan2
- LRIG3 | c.1505C>T p.T502M | Missense Mutation (SNP) | VAF 45/189 reads (24%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.997); catalogued as rs762474881, COSV57871320; called by muse, mutect2, varscan2
- ME1 | c.1271C>G p.T424S | Missense Mutation (SNP) | VAF 38/97 reads (39%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.655); catalogued as COSV63841611, COSV63843281; called by muse, mutect2, varscan2
- MICAL1 | c.994C>A p.R332S | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as COSV62194472; called by muse, varscan2
- MYC | c.1076A>G p.H359R (on ENST00000377970; = p.H374R on NM_002467.6) | Missense Mutation (SNP) | VAF 62/89 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52367783; called by muse, mutect2, varscan2
- OR10G8 | c.174C>G p.Y58* | Nonsense Mutation (SNP) | VAF 70/170 reads (41%) | catalogued as COSV70909590; called by muse, mutect2, varscan2
- OR5M8 | c.734C>A p.T245K | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV100510820, COSV59118567; called by muse, mutect2, varscan2
- PAMR1 | c.184G>A p.V62M | Missense Mutation (SNP) | VAF 44/119 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV53510233; called by muse, mutect2, varscan2
- PCDHGA2 | c.1873G>A p.E625K | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.972); catalogued as COSV53906010; called by muse, mutect2, varscan2
- PIPOX | c.158G>A p.R53Q | Missense Mutation (SNP) | VAF 33/105 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs138767877; called by muse, mutect2, varscan2
- PLK2 | c.2007A>T p.L669F | Missense Mutation (SNP) | VAF 40/147 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV57110759; called by muse, mutect2, varscan2
- PRICKLE3 | c.1607C>T p.A536V | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.005); catalogued as rs1462689882, COSV66234341; called by muse, mutect2, varscan2
- SEC14L4 | c.919T>G p.F307V | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55402057; called by muse, mutect2, varscan2
- SF3B1 | c.2007A>T p.Q669H | Missense Mutation (SNP) | VAF 58/137 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59230301; called by muse, mutect2, varscan2
- SLC5A10 | c.191C>T p.A64V | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs929593302, COSV58763141; called by muse, mutect2, varscan2
- SORCS2 | c.1592G>C p.G531A | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV61185623; called by muse, mutect2, varscan2
- TNIK | c.3217C>T p.R1073* | Nonsense Mutation (SNP) | VAF 34/94 reads (36%) | catalogued as COSV52699763; called by muse, mutect2, varscan2
- TNPO1 | c.2329G>C p.E777Q | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.799); catalogued as COSV61521154, COSV61524573; called by muse, mutect2, varscan2
- VSIR | c.166C>T p.L56F | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT tolerated (0.12); PolyPhen benign (0.343); catalogued as rs1296226004, COSV56495439; called by muse, mutect2, varscan2
- ZNF292 | c.844C>T p.R282C | Missense Mutation (SNP) | VAF 39/137 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs981995863, COSV60548490; called by muse, mutect2, varscan2
- ZNF700 | c.1337A>G p.Y446C | Missense Mutation (SNP) | VAF 21/64 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.085); catalogued as rs189372843, COSV54315920; called by muse, mutect2, varscan2
- ZNF804A | c.664G>C p.A222P | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100168502, COSV56476000; called by muse, mutect2, varscan2
- ARID5B | c.1788del p.S597Afs*32 | Frame Shift Del (DEL) | VAF 8/27 reads (30%) | called by mutect2, pindel, varscan2
- CHD4 | c.3531_3533del p.K1178del (on ENST00000357008 / NM_001363606.2; = p.K1191del on NM_001273.5) | In Frame Del (DEL) | VAF 36/85 reads (42%) | called by pindel, varscan2
- PBRM1 | c.773dup p.N258Kfs*6 | Frame Shift Ins (INS) | VAF 79/250 reads (32%) | called by mutect2, pindel, varscan2
- SIN3A | c.1439_1447del p.Y480_N482del | In Frame Del (DEL) | VAF 37/51 reads (73%) | called by mutect2, pindel, varscan2
- CAGE1 | c.1579A>C p.R527= (on ENST00000512086; = p.R391= on NM_205864.3) | Silent (SNP) | VAF 26/238 reads (11%) | catalogued as COSV57083307; called by muse, mutect2
- CD7 | c.153C>T p.S51= | Silent (SNP) | VAF 17/29 reads (59%) | catalogued as rs745737735, COSV53941119; called by muse, mutect2, varscan2
- CDH17 | c.300C>T p.D100= | Silent (SNP) | VAF 40/183 reads (22%) | catalogued as rs747266533, COSV50345797; called by muse, mutect2, varscan2
- CPT1C | c.1515G>A p.P505= | Silent (SNP) | VAF 6/23 reads (26%) | catalogued as rs776922738, COSV54918541; called by muse, mutect2, varscan2
- HLCS | c.1470G>A p.P490= | Silent (SNP) | VAF 15/55 reads (27%) | catalogued as rs775832153, COSV60792765; called by muse, mutect2, varscan2
- IRS4 | c.1128C>G p.R376= | Silent (SNP) | VAF 14/23 reads (61%) | catalogued as COSV64536530; called by muse, mutect2, varscan2
- LRRTM2 | c.1401C>G p.L467= | Silent (SNP) | VAF 44/152 reads (29%) | catalogued as COSV51226185; called by muse, mutect2, varscan2
- LTBP3 | c.558C>T p.Y186= | Silent (SNP) | VAF 5/13 reads (38%) | catalogued as rs766097932, COSV57240184; called by muse, mutect2, varscan2
- MCM3 | c.660C>T p.A220= (on ENST00000229854 / NM_001366374.2; = p.A210= on NM_002388.6 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 10/36 reads (28%) | catalogued as rs112388885, COSV57719868; called by muse, mutect2, varscan2
- MYH7 | c.1119G>A p.A373= | Silent (SNP) | VAF 28/88 reads (32%) | catalogued as rs572672362, COSV62524712; ClinVar: uncertain significance / likely benign / benign; called by muse, mutect2, varscan2
- RECQL4 | c.1431G>C p.G477= | Silent (SNP) | VAF 16/36 reads (44%) | catalogued as COSV52883608; called by muse, mutect2, varscan2
- RIMBP2 | c.1704C>T p.S568= | Silent (SNP) | VAF 7/12 reads (58%) | catalogued as rs753678065, COSV55464945; called by muse, mutect2, varscan2
- SEMA4B | c.1125G>A p.K375= | Silent (SNP) | VAF 12/29 reads (41%) | catalogued as COSV60176323; called by muse, mutect2, varscan2
- SHLD1 | c.69G>A p.A23= | Silent (SNP) | VAF 21/69 reads (30%) | catalogued as rs202050628, COSV57440205; called by muse, mutect2, varscan2
- SIRPB1 | c.1098T>C p.A366= | Silent (SNP) | VAF 19/49 reads (39%) | catalogued as COSV53541416; called by muse, mutect2, varscan2
- SMC6 | c.2577A>G p.E859= | Silent (SNP) | VAF 111/220 reads (50%) | catalogued as COSV61179232; called by muse, mutect2, varscan2
- SUMF2 | c.228G>T p.A76= (on ENST00000652303; = p.A57= on NM_015411.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 23/58 reads (40%) | catalogued as COSV51908161; called by muse, mutect2, varscan2
